Somatic mutation profile of tumor specimen C3L-00881-71 (aliquot CPT0017040007) from CPTAC case C3L-00881, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 80.3 years (29,330 days).
Specimen C3L-00881-71: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bfd984f-0053-4ba2-9772-5f6c47f266b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00881-31 (Blood Derived Normal), aliquot CPT0015340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d90aa76-2f4c-4d12-93a6-7cb9231292fb

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, 3'Flank 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGAP3 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs920474954; called by muse, mutect2
- ASIC3 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.087); catalogued as rs1414105389; called by muse, mutect2
- CORO6 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61471869; called by muse, mutect2
- HLA-DRB5 | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs184544272; called by muse, varscan2
- IGSF10 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372867906; called by muse, mutect2
- KCNA3 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV63902586; called by muse, mutect2
- PCDHA9 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 65/1405 reads (5%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.014); catalogued as COSV65333780; called by muse, mutect2
- POMT2 | c.745A>T p.I249F | Missense Mutation (SNP) | VAF 32/562 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1337866102; called by muse, mutect2
- ASXL1 | c.68A>G p.N23S | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- CHAT | c.2097C>A p.C699* | Nonsense Mutation (SNP) | VAF 16/431 reads (4%) | called by muse, mutect2
- HSPB9 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.368); called by muse, mutect2
- LY6G6E | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 50/704 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP3K20 | c.460_462del p.A154del | In Frame Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- SAMD9 | c.2287C>G p.L763V | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.295); called by muse, mutect2
- FLG2 | c.6468A>G p.R2156= | Silent (SNP) | VAF 15/171 reads (9%) | called by muse, mutect2
- GPR50 | c.1668C>T p.D556= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as rs747548013, COSV54441311; called by muse, mutect2, varscan2
- H3C11 | c.246T>C p.D82= | Silent (SNP) | VAF 25/459 reads (5%) | catalogued as rs1185788053; called by muse, mutect2
- SLC35A2 | c.843C>T p.G281= | Silent (SNP) | VAF 22/208 reads (11%) | catalogued as rs782406133; called by muse, mutect2
- ATP1A1 | chr1:116405719 A>G | 3'Flank (SNP) | VAF 12/246 reads (5%) | called by muse, mutect2
